Gene-level copy-number profile of tumor specimen TCGA-W5-AA2W-01A from TCGA case TCGA-W5-AA2W, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 31.3 years (11,438 days).
Specimen TCGA-W5-AA2W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CHOL.a9abae69-e82c-46f5-a1e4-6c8045c6a1de.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-W5-AA2W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/30347b02-b585-40f9-a204-6ecfacdc0b1d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,914; copy number 2: 44,604; copy number 3: 4,693; copy number 4: 1,009; copy number 5: 365; copy number 6: 1,230.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-W5-AA2W-01A-11D-A416-01): tumor purity 0.87, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,595 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:169,662,007–169,854,080, 1 gene, copy number 6 (within-gene range 4–6): C1orf112.
- chr1:169,722,640–248,919,946, 1,594 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,914. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
